Gene-level copy-number profile of tumor specimen C3L-04760-01 from CPTAC case C3L-04760, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 83.1 years (30,367 days).
Specimen C3L-04760-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file de45614f-cf9b-4904-aade-80b6f037be13.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04760-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/a0cf6164-f678-4677-9b8c-6c3e37021c9d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 8,829; copy number 2: 49,206; copy number 3: 850.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,715,443–7,896,716, 18 genes: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A.
- chr10:87,607,985–88,584,530, 15 genes: AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
